Somatic mutation profile of tumor specimen TCGA-HT-8106-01A (aliquot TCGA-HT-8106-01A-11D-2395-08) from TCGA case TCGA-HT-8106, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 53.5 years (19,555 days).
Specimen TCGA-HT-8106-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc772d21-4730-413d-8bbc-2a2df5e094d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-8106-10A (Blood Derived Normal), aliquot TCGA-HT-8106-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb2dba5a-cbac-49e3-83be-7282b961028a

The open-access MAF lists 30 somatic variants for this specimen: 23 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 20, Silent 7, Nonsense Mutation 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 11/64 reads (17%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 30/101 reads (30%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1096G>T p.G366* | Nonsense Mutation (SNP) | VAF 7/123 reads (6%) | catalogued as COSV50958623; called by muse, mutect2
- AL592490.1 | c.1160G>A p.G387E | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as COSV101308308, COSV69425245; called by muse, mutect2
- ASXL3 | c.3853A>G p.I1285V | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV52460851; called by muse, mutect2, varscan2
- BCAM | c.1238C>T p.S413F | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV54300836; called by muse, mutect2, varscan2
- DCLK2 | c.1566+1G>A p.X522_splice | Splice Site (SNP) | VAF 10/132 reads (8%) | catalogued as COSV56201219; called by muse, mutect2
- EBF3 | c.691A>C p.N231H | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62473080; called by muse, mutect2
- GALNT6 | c.1428C>A p.N476K | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as COSV62541845; called by muse, mutect2, varscan2
- GAPVD1 | c.2414A>G p.D805G | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.075); catalogued as COSV52921567; called by muse, mutect2, varscan2
- GAST | c.110G>A p.G37E | Missense Mutation (SNP) | VAF 8/159 reads (5%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.007); catalogued as rs782357713, COSV61475463; called by muse, mutect2
- LSM11 | c.530A>G p.K177R | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.784); catalogued as COSV53847784; called by muse, mutect2
- MMP26 | c.490T>A p.F164I | Missense Mutation (SNP) | VAF 56/257 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56171686; called by muse, mutect2, varscan2
- MUC17 | c.5295G>T p.E1765D | Missense Mutation (SNP) | VAF 91/528 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.286); catalogued as COSV60283109; called by muse, mutect2, varscan2
- MYCBP | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as COSV65931323; called by muse, mutect2, varscan2
- MYCBP2 | c.282T>A p.N94K (on ENST00000357337; = p.N132K on NM_015057.5) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.01); catalogued as COSV62012867; called by muse, mutect2, varscan2
- NCOA2 | c.3170G>A p.G1057D | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.587); catalogued as COSV51218635; called by muse, mutect2
- PCDHB3 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs1208055016, COSV50566047; called by muse, mutect2
- RBPJ | c.1391A>G p.N464S | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as rs1064404, COSV60749778; called by muse, mutect2
- SCN1A | c.2392A>T p.N798Y (on ENST00000303395 / NM_001202435.3; = p.N787Y on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV57664136; called by muse, mutect2, varscan2
- STAB2 | c.3908A>G p.E1303G | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.444); catalogued as COSV66336235; called by muse, mutect2, varscan2
- TH | c.316G>A p.E106K (on ENST00000381178 / NM_199292.3; = p.E75K on NM_000360.4) | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as rs1424936497, COSV60766929; called by muse, mutect2, varscan2
- DDX52 | c.1770G>C p.K590N | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- BEST1 | c.511T>C p.L171= | Silent (SNP) | VAF 33/318 reads (10%) | catalogued as COSV57120149; called by muse, mutect2, varscan2
- CRHBP | c.738G>A p.L246= | Silent (SNP) | VAF 9/117 reads (8%) | catalogued as COSV57187796; called by muse, mutect2
- FAT4 | c.1716C>G p.L572= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV67882794; called by muse, mutect2
- MUC16 | c.17511C>A p.P5837= | Silent (SNP) | VAF 11/137 reads (8%) | catalogued as COSV67453324; called by muse, mutect2
- MYOCD | c.1314T>A p.S438= | Silent (SNP) | VAF 12/156 reads (8%) | catalogued as COSV58499750; called by muse, mutect2
- NKX3-2 | c.861C>G p.R287= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs748730719, COSV66711531, COSV66711889; called by muse, mutect2, varscan2
- SMC1B | c.1995C>T p.C665= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV62528864; called by muse, mutect2, varscan2
